Somatic mutation profile of tumor specimen TCGA-S9-A6TX-01A (aliquot TCGA-S9-A6TX-01A-21D-A32B-08) from TCGA case TCGA-S9-A6TX, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 46.6 years (17,025 days).
Specimen TCGA-S9-A6TX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d55a3584-ee18-4a30-8a74-b444e7a61324.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A6TX-10A (Blood Derived Normal), aliquot TCGA-S9-A6TX-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/220b3adb-2e68-409d-b9bf-16035c3cad09

The open-access MAF lists 37 somatic variants for this specimen: 31 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 27, Silent 6, Frame Shift Del 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 28/70 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ALDH3B2 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 53/195 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs528990160, COSV62429487; called by muse, mutect2, varscan2
- ATP8A1 | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs1217699790, COSV52531992; called by muse, mutect2
- CHRNB1 | c.322G>C p.V108L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.596); catalogued as COSV99548266; called by muse, mutect2, varscan2
- CIC | c.3347dup p.S1117Kfs*34 | Frame Shift Ins (INS) | VAF 31/55 reads (56%) | catalogued as rs761345552; called by mutect2, varscan2
- CTNNB1 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as rs769825609, COSV100846212; called by muse, mutect2, varscan2
- GSTA1 | c.602G>A p.G201D | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100575509; called by muse, mutect2, varscan2
- HENMT1 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100898655; called by muse, mutect2, varscan2
- HOXA9 | c.307C>G p.P103A | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs770972572, COSV100604295; called by muse, varscan2
- KEL | c.1915G>A p.V639I | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs745981653, COSV100787038; called by muse, mutect2, varscan2
- KIAA0895L | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99220490; called by muse, mutect2, varscan2
- KLHL38 | c.871G>A p.G291R | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs377275127; called by muse, mutect2, varscan2
- LY9 | c.1408A>G p.I470V | Missense Mutation (SNP) | VAF 6/119 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.031); catalogued as COSV99626667; called by muse, mutect2
- NAT8 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.041); catalogued as rs539613764, COSV99721995; called by muse, mutect2, varscan2
- OAS3 | c.2506C>T p.R836W | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766861655, COSV99966239; called by muse, varscan2
- OXGR1 | c.950T>G p.V317G | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100036975; called by muse, mutect2, varscan2
- PAK6 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs753819966, COSV99544459; called by muse, mutect2, varscan2
- PPP2R2A | c.88A>G p.I30V | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV100277146; called by muse, mutect2, varscan2
- RABEP2 | c.700A>G p.I234V | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.083); catalogued as rs1300749325, COSV100706978; called by muse, mutect2, varscan2
- RAP1GDS1 | c.902T>C p.L301P (on ENST00000408927 / NM_001100427.2; = p.L302P on NM_021159.5) | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV99216929; called by muse, mutect2
- RNF19B | c.1264G>A p.G422S | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52390449, COSV99331380; called by muse, mutect2, varscan2
- SAMD9 | c.4610A>G p.N1537S | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.066); catalogued as COSV101180217; called by muse, mutect2, varscan2
- SSH3 | c.1615A>G p.R539G | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV100354534, COSV57384900; called by muse, mutect2
- TMC5 | c.2889A>C p.K963N (on ENST00000396229 / NM_001105248.1; = p.K717N on NM_024780.5) | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV99572425; called by muse, mutect2
- TMUB2 | c.925G>A p.V309I (on ENST00000538716 / NM_001353177.2; = p.V289I on NM_024107.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.988); catalogued as rs139203660; called by muse, varscan2
- TNKS1BP1 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs777018298, COSV100835990; called by muse, mutect2, varscan2
- WDR81 | c.4501C>T p.R1501W (on ENST00000409644 / NM_001163809.2; = p.R450W on NM_152348.4) | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs777469137, COSV100488821; called by muse, mutect2, varscan2
- ZMYND12 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs763516313, COSV100999813; called by muse, mutect2, varscan2
- FUBP1 | c.1535del p.N512Mfs*153 | Frame Shift Del (DEL) | VAF 23/43 reads (53%) | called by mutect2, pindel, varscan2
- IRF9 | c.747_748insAC p.S250Tfs*24 | Frame Shift Ins (INS) | VAF 30/73 reads (41%) | called by mutect2, pindel*, varscan2*
- ZBTB33 | c.1969_1970del p.V657Nfs*6 | Frame Shift Del (DEL) | VAF 6/51 reads (12%) | called by mutect2, pindel, varscan2
- C3 | c.2679G>A p.S893= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as rs778577015, COSV99836538; called by muse, mutect2
- CDH13 | c.138G>A p.E46= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV99225370; called by muse, mutect2
- DNAH3 | c.1026G>A p.E342= | Silent (SNP) | VAF 53/131 reads (40%) | catalogued as COSV99767026; called by muse, mutect2, varscan2
- GPR45 | c.363C>T p.G121= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV51522980; called by muse, mutect2, varscan2
- GRM8 | c.2694A>G p.T898= | Silent (SNP) | VAF 54/131 reads (41%) | catalogued as COSV100282619; called by muse, mutect2, varscan2
- MYO3A | c.1531C>T p.L511= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as rs1335980755, COSV99779068, COSV99780341; called by muse, mutect2, varscan2
